Somatic mutation profile of tumor specimen TCGA-76-6192-01A (aliquot TCGA-76-6192-01A-11D-1696-08) from TCGA case TCGA-76-6192, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.8 years (27,322 days).
Specimen TCGA-76-6192-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5dc066f-d33d-495f-815c-2da864bf2d82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6192-10A (Blood Derived Normal), aliquot TCGA-76-6192-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa361fc3-4377-4193-aad0-3690d3e6d8eb

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 35, Silent 15, Nonsense Mutation 2, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | hotspot (GDC flag); catalogued as rs1257124719, COSV100909782, COSV64290925, COSV64293353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS10 | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs782238413, COSV54354409; called by muse, mutect2, varscan2
- ADGRL4 | c.396A>T p.K132N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV66061364; called by muse, mutect2, varscan2
- ANLN | c.2960G>C p.R987T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs747031560, COSV56075722; called by muse, mutect2, varscan2
- CYP27B1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV56984632; called by muse, mutect2, varscan2
- CYP4A11 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs765836836, COSV60223334; called by muse, mutect2, varscan2
- EHMT2 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64995831; called by muse, mutect2, varscan2
- FRAS1 | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774652198, COSV53607118; called by muse, mutect2, varscan2
- GAK | c.2957A>G p.N986S | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs200252102, COSV58504344; called by muse, mutect2, varscan2
- ITGA8 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538437434, COSV65228152; called by muse, mutect2, varscan2
- ITGAX | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs777199815, COSV51645222; called by muse, mutect2, varscan2
- KLF17 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.149); catalogued as rs994439989, COSV64856240; called by muse, mutect2
- LHX9 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV61328439; called by muse, mutect2, varscan2
- LUZP4 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs201126715, COSV64218411; called by muse, mutect2, varscan2
- MMP7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs145006821; called by muse, mutect2, varscan2
- MNDA | c.722C>A p.A241D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63740677; called by muse, mutect2, varscan2
- MUC17 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as rs777479634, COSV60283635; called by muse, mutect2, varscan2
- NFIB | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV66620594; called by muse, mutect2, varscan2
- NLRP5 | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as rs778188316, COSV66764200; called by muse, mutect2, varscan2
- PCDHA13 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); catalogued as COSV56497250; called by muse, mutect2, varscan2
- PCDHA6 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.366); catalogued as COSV100972215, COSV100972507; called by muse, mutect2, varscan2
- PCDHGA3 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV53924769; called by muse, mutect2, varscan2
- PCLO | c.2644C>T p.R882* | Nonsense Mutation (SNP) | VAF 103/469 reads (22%) | catalogued as COSV61619487; called by muse, mutect2, varscan2
- PLEKHA5 | c.1379C>G p.T460R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV54699530; called by muse, mutect2, varscan2
- PMPCA | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs776990571, COSV65509488; called by muse, mutect2, varscan2
- SCN7A | c.4272G>T p.M1424I | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV69271086; called by muse, mutect2, varscan2
- SIGLEC14 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV55779392; called by muse, mutect2, varscan2
- SIM2 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748878245, COSV51768389; called by muse, mutect2, varscan2
- SLC1A6 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as rs996260256, COSV55667680; called by muse, mutect2, varscan2
- SLC26A8 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as rs201650524, COSV62885138; called by muse, mutect2, varscan2
- SLC66A3 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs772295244, COSV54466908; called by muse, mutect2, varscan2
- SPAG5 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs760085759, COSV58801469; called by muse, mutect2, varscan2
- SRSF5 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 62/244 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as COSV67936718; called by muse, mutect2, varscan2
- THSD7B | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as rs756145411, COSV55681477, COSV99745816; called by muse, mutect2, varscan2
- TPRG1 | c.763A>T p.M255L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV61464875; called by muse, mutect2, varscan2
- TRIO | c.3997A>G p.I1333V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs770762103, COSV60082889; called by muse, mutect2, varscan2
- TSHZ2 | c.970G>A p.V324I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as rs138844500, COSV61592313; called by muse, mutect2, varscan2
- TTC6 | c.591+1G>T p.X197_splice (on ENST00000267368; = p.X1563_splice on NM_001310135.3) | Splice Site (SNP) | VAF 18/106 reads (17%) | catalogued as COSV99941789; called by muse, mutect2, varscan2
- UGT1A6 | c.677T>G p.F226C | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV59388075; called by muse, mutect2, varscan2
- AP3B1 | c.870G>A p.P290= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs566729844, COSV54882712; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP8A2 | c.2556C>T p.Y852= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs374883147; called by muse, mutect2, varscan2
- ETNPPL | c.1266A>G p.A422= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs372406167; called by muse, mutect2, varscan2
- GCAT | c.597G>A p.V199= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV50648945; called by muse, mutect2, varscan2
- GRK7 | c.855G>A p.T285= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs377371842; called by muse, mutect2, varscan2
- OR52E4 | c.786A>T p.T262= | Silent (SNP) | VAF 33/149 reads (22%) | catalogued as COSV57624556; called by muse, mutect2, varscan2
- PLEKHA3 | c.687A>T p.V229= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as COSV52293954; called by muse, mutect2, varscan2
- RASSF6 | c.69C>A p.S23= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV56718224; called by muse, mutect2, varscan2
- RGMB | c.690A>G p.K230= (on ENST00000513185 / NM_001366508.1; = p.K271= on NM_001012761.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57565393; called by muse, mutect2, varscan2
- SEMA6D | c.501A>G p.P167= | Silent (SNP) | VAF 37/137 reads (27%) | catalogued as COSV60376521; called by muse, mutect2, varscan2
- SPATS2L | c.522A>C p.S174= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV62347819; called by muse, mutect2, varscan2
- SPDL1 | c.1443G>A p.P481= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs529689293, COSV54667931; called by muse, mutect2, varscan2
- TMC1 | c.2136C>T p.A712= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV52774398; called by muse, mutect2, varscan2
- TNS3 | c.3594C>T p.D1198= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV60790426; called by muse, mutect2, varscan2
- ZSCAN31 | c.48G>A p.E16= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV60180773; called by muse, mutect2, varscan2
